Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A2PP, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A2PP-01A (Primary Tumor).

[page 1 of 2]
IIIIAA Discrepancy		☒

for 8/31/11

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type: **INPATIENT**
Additional Copy to:

Clinical Diagnosis & History:

year old male with thyroid nodule (+) papillary in FNA, papillary carcinoma.

Specimens Submitted:

1: Thyroid; total thyroidectomy

DIAGNOSIS:

1. Thyroid; total thyroidectomy:

Tumor Type:

Papillary carcinoma, follicular variant
with oncocytic features

Histologic Grade:

Well differentiated

Mitotic Activity:

Mild to moderate
Two mitosis /10 high power fields

Tumor Necrosis:

Not identified

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 3.6 cm.

Tumor Encapsulation:

Completely surrounded

Capsular Invasion:

Not identified

Blood Vessel Invasion:

Not identified

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

One separate papillary microcarcinoma (0.08cm) in left lobe

Non-Neoplastic Thyroid:

ICD-0-3
carcinoma, papillary, follicular variant
8340/3
Site: thyroid, NOS 673.9
for
8/31/11

[page 2 of 2]
shows a few hyperplastic nodules.
Parathyroid Glands:
Not identified

Lymph Nodes:
Three benign lymph nodes (0/3)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	
	RECUT	

Gross Description:

1). The specimen is received fresh and subsequently placed in formalin, labeled "total thyroidectomy, double stitch marks superior pole, fresh and sterile, TPS" and consists of a 40 g thyroid. The right lobe measures 5 x 3.5 x 2.5 cm with an anteriorly attached 6 x 2 x 1.3 cm portion of red-pink, striated muscle tissue. The left lobe measures 3.9 x 1.9 x 1.5 cm and the isthmus measures 2.4 x 1.5 x 1 cm. Superior attached to the isthmus, toward the left lobe, is the pyramidal lobe, measuring 2.3 x 0.8 x 0.5 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals a 3.6 x 3.5 x 2.5 cm tan-pink, finely lobular, circumscribed nodule in the right upper to mid lobe. The nodule does not appear to extend to the isthmus. The remaining thyroid parenchyma is red tan and meaty. A portion of the specimen is sent for TPS. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

RL - right lobe
LL - left lobe
IS - isthmus
PL - pyramidal lobe

Summary of Sections:**Part 1: Thyroid; total thyroidectomy**

Block	Sect. Site	PCs
5	IS	9
8	LL	14
2	PL	7
24	RL	24

Source: NCI Genomic Data Commons file 3df97d8d-0edf-4105-92dd-543ebb8faa0d (TCGA-DJ-A2PP.EE368CF1-9955-49B2-9EBA-3F6E37EE8D46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).